Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6906, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6906-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

CARD CASE COMMENT:

FIRST PATHOLOGY DATE

FIRST PATHOLOGY REPORT:

PRIMARY PATHOLOGIST: 2

DIAGNOSIS-1 M9593 MALIGNANT LYMPHOMA, NOS

SPECIMEN-1 T07 SPLEEN

[page 2 of 2]
TYPE OF BONE MARROW		FUNCTIONALITY		CELLULARITY		CELLULARITY	
☐ UNAVAILABLE ☐ FUNCTIONAL ☐ PARTICULATE ☐ AMPLIFIED		☒ YES ☐ NO ☐ YES ☐ NO		☐ PLASTIC ☐ PLASTIC		RANGE: _____ () to _____ () AVERAGE: 45.55 % to _____ () UNEVALUABLE ☐	
LEUKEMIC CELL COUNT				☐ NOT APPLICABLE ☐ MYELOBLASTS & PROMYELOCYTES ☐ MEGAKARYOBLASTS			
☐ MONOBLASTS + PROMONOCYTES AS A % OF ALL NUCLEATED CELLS (ANC) PER HPF (400 x field)				☐ LYMPHOBLASTS + LYMPHOCYTES ☐ 0-10 ☐ 10-30 ☐ 30-55 ☐ > 55 ☐ 0-10 ☐ 10-30 ☐ 30-100 ☐ > 100			
CLONES: ☐ YES ☐ NO ☐ NOT EVALUABLE EOSINOPHILIA: ☐ NONE ☐ SPARSE ☐ MARKED BASOPHILIA: ☐ NONE ☐ SPARSE ☐ MARKED				M.E. RATIO: 3.2 : 1			
NORMAL OR DYSPLASTIC HEMOPOIESIS							
☐ NOT EVALUABLE (Cytology unavailable)							
CELLULARITY: LOW NORMAL HIGH DYSPL							
GRANULOCYTES: ☐ 0 ☐ 1 ☐ 2 ☒ 3 ☐ 4 ☐ 5 ☐ Y ☒ N							
ERYTHROIDS: ☐ 0 ☐ 1 ☐ 2 ☒ 3 ☐ 4 ☐ 5 ☐ Y ☒ N							
MONOCYTES: ☐ 0 ☐ 1 ☐ 2 ☒ 3 ☐ 4 ☐ 5 ☐ Y ☒ N							
LYMPHOCYTES: ☐ 0 ☐ 1 ☒ 2 ☐ 3 ☐ 4 ☐ 5 ☐ Y ☒ N							
MEGAKARYOCYTES/HPF: 6 RANGE: _____ to _____ MEAN 2.2 ☐ Y ☒ N							
MYELOFIBROSIS: ☒ NOT EVALUABLE (special stains unavailable)							
☒ H&E/PAS/GIEMSA ☐ RETICULIN STAIN ☐ COLLAGEN STAIN							
GRADE:							
☐ 1 = NO INCREASE IN RETICULIN ☐ 2 = FOCAL INCREASE IN RETICULIN ☐ 3 = DIFFUSE INCREASE IN RETICULIN ☐ 4 = DIFFUSE INCREASE IN RETICULIN AND COLLAGEN ☐ 5a = COLLAGEN CONSPICUOUS, ARCHITECTURE DISTORTION 3+ ☐ 5b = GRADE 5a PLUS NEW BONE FORMATION (OSTEOSCLEROSIS)							
INFILTRATES OTHER THAN NOTED ABOVE UNDER LEUKEMIC CELL COUNT:							
☒ NONE ☐ SHEETS ☐ NODULES							
☐ NUMBER: _____ / HPF: TOTAL NO. _____							
☐ PARATRABECULAR ☐ INTERSTITIAL ☐ CARCINOMA ☐ LYMPHOID ☐ PLASMACYTIC ☐ BORDERLINE ☐ REACTIVE ☐ NEOPLASTIC ☐ OTHER _____							
PROPORTION OF SECTION INFILTRATED:							
RIGHT ILIAC CREST % AVERAGE: % LEFT ILIAC CREST % ASPIRATE: %							
MARROW IMPRINT/SMEAR DIF. COUNT							
☐ NOT AVAILABLE							
CELLULARITY: 2+3+ MYELOBLASTS: 0.6% CELLS COUNTED: 500 PROMYELOCYTES: 1.0% PLATELETS: mk. inc. MYELOCYTES: 5.0% MEGAKARYOCYTES: inc. METAMELOCYTES: 9.4% MEGAKARYOBLASTS: STABS: 28.6% Auer rods: SEGMENTED: 21.6%							
% NEUTRO. % EOS. % BASO. MONOBLASTS: 0.6% PROMONOCYTES: 4.2% MONOCYTES: 21.2% LYMPHOBLASTS: 5.4% LYMPHOCYTES: 5.4% PLASMA CELLS: 0.6% HISTIOCYTES: 0.2% SIDEROBLASTS: 0.2% OTHER: 0.2%							
CBO: HGB 12.5 g/dl THERAPY: ☐ NO ☒ OP ☐ RT ☐ TRANSP. WBC 8.65 x 10 ⁹ /L PLT 104 x 10 ⁹ /L LAST DATE: _____							
CYTOCHEMICAL SCORE (%):							
CELLS: % PX SB CAE ANBE ANAE AP TRAP PAS OTHER							
TOTAL:							
BLASTS:							
DIAGNOSIS (see reverse side for abbreviated keys)							
ORDERLY GRANULOPOIESIS AND ERYTHROPOIESIS. MODERATE MEGAKARYOCYTIC HYPERPLASIA. NEGATIVE FOR LYMPHOMA. CELLULARITY 55%. LYMPHOCYTES 5.4%. RIGHT AND LEFT ILIAC CREST BIOPSIES, SECTIONS, IMPRINTS AND SMEARS							
IMMUNO PHENOTYPE:							
SIGNED: _____ M.D. SIGNED: _____ M.D. (ATTENDING PATHOLOGIST)							

PATHOLOGY FILE

Source: NCI Genomic Data Commons file 02a1fe95-1169-4ce1-803d-1d2222b454c2 (TCGA-G8-6906.78E17250-F41C-49AF-8738-945CBBA5C937.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).